Somatic mutation profile of tumor specimen MMRF_1574_1_BM_CD138pos (aliquot MMRF_1574_1_BM_CD138pos_T1_KBS5U_L03501) from MMRF case MMRF_1574, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.9 years (24,085 days).
Specimen MMRF_1574_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d732f9b-92e0-4875-a0e2-166b5062e884.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1574_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1574_1_PB_Whole_C2_KBS5U_L03505; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bee0c2c7-ecb7-4217-9e62-19934fb47718

The open-access MAF lists 157 somatic variants for this specimen: 53 protein-altering or splice-affecting, 25 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 45, Silent 25, Intron 15, 5'UTR 9, 5'Flank 4, 3'Flank 3, RNA 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD52 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1459764200; called by muse, mutect2
- ARHGEF19 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs762419098; called by muse, mutect2, varscan2
- ARHGEF28 | c.910+1G>A p.X304_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as rs1051486394; called by muse, mutect2
- CASP6 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs376919922, COSV99488619; called by muse, mutect2, varscan2
- COL9A1 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1230735308; called by muse, mutect2
- GNAI2 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56493222; called by muse, mutect2
- GRM7 | c.1749A>C p.K583N | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV63179206; called by muse, mutect2
- H4C11 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs773266406; called by muse, mutect2, varscan2
- IGHD7-27 | c.5C>G p.T2S | Missense Mutation (SNP) | VAF 19/19 reads (100%) | PolyPhen possibly damaging (0.908); catalogued as rs187067877; called by muse, mutect2, varscan2
- IGHJ5 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | PolyPhen benign (0.05); catalogued as rs377429542; called by muse, varscan2
- IGHV2-70 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs377473012; called by muse, varscan2
- IGHV2-70 | c.147C>G p.S49R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376260160; called by muse, varscan2
- IGKV2-24 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs374129730; called by muse, varscan2
- ITPR1 | c.1609C>T p.R537W (on ENST00000354582; = p.R522W on NM_002222.7) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1325295506; called by muse, mutect2, varscan2
- KCNG1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs1323040650; called by muse, mutect2
- KIF1C | c.3265C>T p.R1089W | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs780451511; called by muse, mutect2
- LARGE2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs766173362; called by muse, mutect2
- MBD5 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV68696473; called by muse, mutect2, varscan2
- OBSCN | c.3268del p.A1090Pfs*5 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as COSV52739757; called by mutect2, pindel, varscan2
- OGT | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101035579, COSV65481013, COSV65482385; called by muse, mutect2, varscan2
- PDZD3 | c.1238C>T p.A413V (on ENST00000531114; = p.A333V on NM_024791.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs150334070; called by muse, mutect2, varscan2
- PTPRA | c.738C>T p.N246= | Splice Region (SNP) | VAF 12/150 reads (8%) | catalogued as rs567282541; called by muse, mutect2
- SLC6A2 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1246524447; called by muse, mutect2, varscan2
- TMEM202 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as rs779515152, COSV58982182, COSV58983721; called by muse, mutect2, varscan2
- TRABD2B | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361634805; called by muse, mutect2
- TTN | c.54059G>A p.G18020D (on ENST00000591111; = p.G10596D on NM_003319.4) | Missense Mutation (SNP) | VAF 26/205 reads (13%) | PolyPhen probably damaging (1); catalogued as rs397517640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA5B2 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374950252; called by muse, mutect2
- B3GAT1 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- B3GNT6 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- B4GALT7 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- CAT | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CD22 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CTPS2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DSCAML1 | c.1964-2del p.X655_splice (on ENST00000321322; = p.X595_splice on NM_020693.4) | Splice Site (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- H2AC17 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- H2BC9 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- HNRNPUL1 | c.605A>C p.D202A | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KIAA1109 | c.14444T>C p.M4815T | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KNDC1 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NFX1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- OOSP1 | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- PCLO | c.5294C>G p.P1765R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- PLEKHH2 | c.3445A>G p.T1149A | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PPM1K | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PPP1R9A | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- RTTN | c.6313C>A p.L2105I | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- SACS | c.7629G>C p.K2543N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- TENT5C | c.691A>C p.I231L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- TNFRSF8 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- UBE2C | c.31_45del p.T11_A15del | In Frame Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- WDR45 | c.641G>A p.G214D (on ENST00000376372 / NM_001029896.2; = p.G215D on NM_007075.3) | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM2 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZHX2 | c.1599C>G p.F533L | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.294); called by muse, mutect2
- ADAD2 | c.249G>A p.A83= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs925798020, COSV51895868; called by muse, mutect2, varscan2
- ASB15 | c.720G>A p.A240= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs553190475, COSV51927863; called by muse, mutect2
- B2M | c.285A>G p.K95= | Silent (SNP) | VAF 12/251 reads (5%) | catalogued as COSV62562999; called by muse, mutect2
- BTG1 | c.108G>A p.Q36= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs533912735, COSV55457953, COSV55458217, COSV55458575; called by muse, mutect2, varscan2
- CCDC171 | c.1176T>C p.N392= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- GNAL | c.462C>T p.N154= (on ENST00000269162 / NM_001142339.3; = p.N231= on NM_182978.4) | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs1175867240; called by muse, mutect2
- GRAMD1A | c.1206G>A p.K402= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- HOXD13 | c.342G>A p.A114= | Silent (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- HTT | c.7311G>A p.V2437= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.231T>C p.S77= | Silent (SNP) | VAF 62/71 reads (87%) | catalogued as rs573556742; called by muse, varscan2
- MPPED1 | c.600C>T p.T200= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs781362661, COSV101342288; called by muse, mutect2, varscan2
- MS4A14 | c.807T>A p.S269= | Silent (SNP) | VAF 30/418 reads (7%) | called by muse, mutect2
- NPY5R | c.15C>T p.L5= | Silent (SNP) | VAF 34/380 reads (9%) | catalogued as COSV58453682; called by muse, mutect2
- PCDHA4 | c.1869C>T p.R623= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs782158159, COSV63543046; called by muse, mutect2
- PDE4B | c.1722G>A p.L574= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- PEX12 | c.855T>A p.P285= | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- PHF14 | c.645A>C p.R215= | Silent (SNP) | VAF 91/181 reads (50%) | called by muse, mutect2, varscan2
- POU3F4 | c.618C>T p.I206= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100937320, COSV64538812; called by muse, mutect2, varscan2
- REL | c.1758A>T p.P586= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- RPS12 | c.228A>C p.L76= | Silent (SNP) | VAF 121/259 reads (47%) | called by muse, mutect2, varscan2
- SBF1 | c.225C>T p.S75= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs765171943; called by muse, mutect2, varscan2
- SLC12A5 | c.3384C>T p.R1128= (on ENST00000454036 / NM_001134771.2; = p.R1105= on NM_020708.5) | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs974876670; called by muse, mutect2, varscan2
- SPRR2A | c.189C>T p.C63= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- TRBC2 | c.252C>A p.A84= | Silent (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2, varscan2
- ZNF804B | c.2823A>G p.S941= | Silent (SNP) | VAF 82/173 reads (47%) | catalogued as rs767661840; called by muse, mutect2
- AC009053.1 | n.418C>G | RNA (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- ACKR2 | c.-37-8231G>T | Intron (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- ACYP1 | c.84+3612G>T | Intron (SNP) | VAF 14/88 reads (16%) | called by mutect2, varscan2
- ANO3 | c.*1647T>C | 3'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.*924T>C | 3'UTR (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- AVPR1A | c.-55C>T | 5'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- BAD | c.*333G>C | 3'UTR (SNP) | VAF 25/224 reads (11%) | called by muse, mutect2, varscan2
- BCL2L2 | c.*985G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- BZW2 | c.*64A>G | 3'UTR (SNP) | VAF 69/598 reads (12%) | catalogued as COSV51754346; called by muse, mutect2, varscan2
- CACNG8 | c.*3910G>A | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- CLCNKA | chr1:16036274 T>A | 3'Flank (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2
- CNR1 | c.*1744G>A | 3'UTR (SNP) | VAF 33/97 reads (34%) | catalogued as rs975212238; called by muse, mutect2, varscan2
- COLCA2 | chr11:111295048 C>T | 5'Flank (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- CRISP3 | chr6:49727516 T>C | 3'Flank (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- CTSL3P | n.310C>T | RNA (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- CUL3 | c.-322T>A | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs1210419245; called by muse, mutect2, varscan2
- DAPK1 | c.62+21G>A | Intron (SNP) | VAF 103/205 reads (50%) | called by muse, mutect2, varscan2
- DCTD | c.-8+430C>A | Intron (SNP) | VAF 23/53 reads (43%) | catalogued as rs777882334; called by muse, mutect2, varscan2
- DHDDS | c.*1083C>G | 3'UTR (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- EIF5B | c.*233C>A | 3'UTR (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- ELF2 | c.239-119T>A | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- ERCC2 | c.6-46G>C | Intron (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- F11 | c.485+539G>C | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- FAM220A | c.*62G>T | 3'UTR (SNP) | VAF 36/392 reads (9%) | catalogued as rs569803607; called by muse, mutect2
- FOXA2 | c.*413A>G | 3'UTR (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- GNA14 | c.-207G>A | 5'UTR (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- H2BC9 | c.*80C>T | 3'UTR (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- H3-3A | c.282+958C>T | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2
- HTRA3 | c.1051+1596G>A | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- IBA57 | c.*140G>A | 3'UTR (SNP) | VAF 5/75 reads (7%) | catalogued as rs901258951; called by muse, mutect2
- IGF1R | c.*5426A>G | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- JADE1 | c.1503+1271G>T | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- LILRB2 | chr19:54274185 T>A | 3'Flank (SNP) | VAF 80/130 reads (62%) | called by muse, mutect2, varscan2
- LIN28B | c.*1431del | 3'UTR (DEL) | VAF 4/44 reads (9%) | catalogued as rs1009818775; called by pindel, varscan2
- LRRC7 | c.647+35184C>A | Intron (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2, varscan2
- MRPL35 | c.*2269C>T | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- NAPB | c.*1754C>T | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- OR52H1 | chr11:5551751 G>T | 5'Flank (SNP) | VAF 74/108 reads (69%) | called by muse, mutect2, varscan2
- OR5L1 | c.*4A>G | 3'UTR (SNP) | VAF 9/275 reads (3%) | called by muse, mutect2
- PBX4 | c.*218T>G | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PDE10A | c.*839A>C | 3'UTR (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- PLAGL1 | c.*265G>T | 3'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- POU2F1 | c.*1996A>G | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- POU4F1 | c.*507T>A | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- PRDM10 | c.295-56C>T | Intron (SNP) | VAF 11/89 reads (12%) | catalogued as rs747335966; called by muse, mutect2, varscan2
- PRLR | c.*6474dup | 3'UTR (INS) | VAF 8/65 reads (12%) | catalogued as rs1469995147; called by mutect2, pindel, varscan2
- PRR23B | c.-132G>A | 5'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- RAB23 | c.*465T>C | 3'UTR (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*3394del | 3'UTR (DEL) | VAF 12/44 reads (27%) | catalogued as rs999860604; called by mutect2, varscan2
- RFFL | c.*236G>A | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- RFK | c.*1464T>A | 3'UTR (SNP) | VAF 143/285 reads (50%) | called by muse, mutect2, varscan2
- RIC8A | c.-633C>T | 5'UTR (SNP) | VAF 13/160 reads (8%) | called by muse, mutect2
- RUBCN | c.*1642G>A | 3'UTR (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- SDAD1 | c.-67G>A | 5'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- SEMA3D | c.*3229A>T | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SERPINB9 | c.*417dup | 3'UTR (INS) | VAF 18/42 reads (43%) | called by mutect2, pindel
- SH3YL1 | c.1+184T>A | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, varscan2
- SLIT2 | c.*532T>C | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- SNX31 | c.*254A>G | 3'UTR (SNP) | VAF 32/71 reads (45%) | catalogued as rs971633431; called by muse, mutect2, varscan2
- SP2 | c.*499C>G | 3'UTR (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- SRPK3 | chrX:153780019 G>A | 5'Flank (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- SRRM4 | c.*1734G>A | 3'UTR (SNP) | VAF 51/121 reads (42%) | catalogued as rs972264171; called by muse, mutect2, varscan2
- SSPOP | n.6210C>T | RNA (SNP) | VAF 11/71 reads (15%) | catalogued as rs199968575; called by muse, mutect2, varscan2
- SSX2IP | c.*1805C>T | 3'UTR (SNP) | VAF 31/94 reads (33%) | catalogued as rs1330329555; called by muse, mutect2, varscan2
- TGFA | c.*1413G>T | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- TIAM1 | c.*1546G>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- TMEM154 | c.*9135A>G | 3'UTR (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- TMEM250 | c.*265C>T | 3'UTR (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- TOB1 | c.-100T>C | 5'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- TPP1 | chr11:6619595 C>T | 5'Flank (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- TRIB2 | c.-506C>T | 5'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- TRIM46 | c.*147C>T | 3'UTR (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- TSC2 | c.-87del | 5'UTR (DEL) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- UGCG | c.*1341T>G | 3'UTR (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- UNC5B | c.*669C>T | 3'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs1178902140; called by muse, mutect2, varscan2
- VPS28 | c.37+22C>T | Intron (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2
- WIPF2 | c.*5661G>A | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- ZIM2 | c.478-82C>A | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2
- ZNF592 | c.*39G>A | 3'UTR (SNP) | VAF 12/106 reads (11%) | catalogued as rs760104070; called by muse, mutect2, varscan2
